Gene-level copy-number profile of tumor specimen HCM-CSHL-0061-C18-01A from HCMI case HCM-CSHL-0061-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,277 days).
Specimen HCM-CSHL-0061-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d37f311-d453-40a6-8199-b81c130b0a96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0061-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/f24d9324-8a84-4abd-8606-54bf6d0812a9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 734; copy number 2: 7,188; copy number 3: 18,954; copy number 4: 16,606; copy number 5: 9,076; copy number 6: 2,829; copy number 7: 1,421; copy number 9: 1,453; copy number 10: 75; copy number 11: 53.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,426,861–18,506,313, 8 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,002 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–525,238, 15 genes, copy number 7: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92.
- chr8:28,316,986–28,343,355, 1 gene, copy number 10 (within-gene range 1–10): PNOC.
- chr8:29,333,064–29,360,222, 3 genes, copy number 9: DUSP4, AC084262.2, AC084262.1.
- chr8:41,261,962–145,066,685, 1,574 genes, copy number 9–11 (broad region; genes not listed).
- chr14:18,614,388–18,699,978, 8 genes, copy number 7–11: CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12, CR383656.3, RPL22P20, CR383656.4.
- chr20:87,250–64,327,972, 1,401 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
